Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6521, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6521-01A (Primary Tumor).

[page 1 of 2]
Examination: Histopathological examination (cito)

Material: 1. Total organ resection – stomach

TCGA – D7 – 6521

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the gastric body

Examination performed on:

Macroscopic description:

Sent material consisting of the stomach, cut out along the greater curvature, sized 17 x 18 cm with the omentum sized 34 x 25 cm.

Tumour sized 6 x 2 x 2.5 cm in the greater curvature. Distance from the proximal end 3.5 cm, from distal end 2.5 cm.

Microscopic description:

Adenocarcinoma male differentiatum partim mucocellulare.

The tumour invades through the full thickness of the stomach wall, vessels, perigastric fat tissue, and reaches the surface of the peritoneum.

Incision lines free of neoplastic lesions.

Part of the omentum free of neoplastic lesions.

Lymph nodes:

1,2 - (periorificial): metastases carcinomatosae in lymphonodis No II/II.

Infiltratio carcinomatosa capsulae lymphonodorum.

3 - (lesser curvature): metastases carcinomatosae in lymphonodis (No VIII/VIII).

Infiltratio carcinomatosa capsulae lymphonodorum.

4 - (greater curvature): metastases carcinomatosae in lymphonodis (No III/III).

Infiltratio carcinomatosa capsulae lymphonodorum.

5 - (peripyloric): metastases carcinomatosae in lymphonodis (No II/IV).

Infiltratio carcinomatosa capsulae lymphonodorum.

Histopathological diagnosis:

Adenocarcinoma male differentiatum partim mucocellulare ventriculi. Poorly differentiated and partially mucocellular adenocarcinoma of the stomach.

Metastases carcinomatosae in lymphonodis (No XV/XVII). Cancer metastases in the lymph nodes (No XV/XVII)

(G3, pT2b, pN2 typus) mixtus sec

[page 2 of 2]
CALL YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 4ae99769-e33a-4755-aad0-c3261ba2dad0 (TCGA-D7-6521.323A32F7-7F32-4794-9A08-7ED129C8339A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).